Somatic mutation profile of tumor specimen TCGA-X7-A8DG-01A (aliquot TCGA-X7-A8DG-01A-11D-A423-09) from TCGA case TCGA-X7-A8DG, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 48.0 years (17,517 days).
Specimen TCGA-X7-A8DG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89e5101c-88a0-4567-a5cd-a2e1f0d772b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X7-A8DG-10A (Blood Derived Normal), aliquot TCGA-X7-A8DG-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4afb0826-eb40-4734-824d-ef1b0d346cba

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSF1R | c.1130G>A p.G377D | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53830048; called by muse, mutect2
- LPCAT1 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as COSV52035755, COSV52037002; called by muse, mutect2
- DNAAF2 | c.216G>A p.P72= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as rs1157352127; called by muse, mutect2
